Somatic mutation profile of tumor specimen ALCH-AFJY-TTP1-A (aliquot ALCH-AFJY-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-AFJY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.3 years (23,125 days).
Specimen ALCH-AFJY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43c1ee29-38cc-4afb-902c-eb030afc755b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFJY-NB1-A (Blood Derived Normal), aliquot ALCH-AFJY-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92b5ce99-0e5e-4866-ba6d-ff393e1a0ba7

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 10, Nonsense Mutation 3, Intron 3, Splice Site 2, Frame Shift Del 2, 3'UTR 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B1 | c.2874G>T p.Q958H | Missense Mutation (SNP) | VAF 66/618 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs761183683; called by muse, mutect2, varscan2
- DMTF1 | c.2135T>C p.I712T | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as rs923303286, COSV57538456; called by muse, mutect2, varscan2
- ERAP1 | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 226/630 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs201856260; called by muse, mutect2, varscan2
- GHRHR | c.468G>T p.R156S | Missense Mutation (SNP) | VAF 125/641 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1485885083; called by muse, mutect2, varscan2
- NTSR1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs753277036; called by muse, mutect2, varscan2
- WDFY4 | c.4811C>G p.S1604C | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV57429415, COSV57432834; called by muse, mutect2
- ABCA4 | c.3751G>T p.E1251* | Nonsense Mutation (SNP) | VAF 120/419 reads (29%) | called by muse, mutect2, varscan2
- AFM | c.1548T>G p.D516E | Missense Mutation (SNP) | VAF 120/552 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- AHRR | c.1310G>T p.C437F | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ANK1 | c.17_20del p.K6Sfs*2 | Frame Shift Del (DEL) | VAF 37/264 reads (14%) | called by mutect2, pindel, varscan2
- ATF7IP | c.3587A>G p.Y1196C | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP13A5 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ATXN7L3 | c.781G>C p.D261H (on ENST00000389384 / NM_001382309.1; = p.D268H on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- C10orf71 | c.4210C>T p.P1404S | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- H2BC12 | c.221T>C p.I74T | Missense Mutation (SNP) | VAF 176/671 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- KCNE5 | c.417_421del p.E140Gfs*84 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- KLHL41 | c.1269-1G>A p.X423_splice | Splice Site (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- LRRC1 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- METTL6 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 58/291 reads (20%) | called by muse, mutect2, varscan2
- NPY5R | c.64A>C p.T22P | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NUDT21 | c.256_258del p.V86del | In Frame Del (DEL) | VAF 74/566 reads (13%) | called by mutect2, pindel, varscan2
- NUP153 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 70/303 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PARD3B | c.2114T>A p.L705* | Nonsense Mutation (SNP) | VAF 51/265 reads (19%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.1040-3_1042delinsTTTTTT p.X347_splice (on ENST00000408927 / NM_001100427.2; = p.X348_splice on NM_021159.5) | Splice Site (ONP) | VAF 7/80 reads (9%) | called by mutect2*, pindel
- SUPT20HL2 | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TRIM10 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF281 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- BCAS3 | c.2001A>G p.P667= (on ENST00000390652 / NM_001353144.2; = p.P652= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/364 reads (21%) | catalogued as rs763911904; called by muse, mutect2, varscan2
- CNTN5 | c.1083G>T p.L361= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs1262443003; called by muse, mutect2, varscan2
- DNAH8 | c.6264G>A p.L2088= | Silent (SNP) | VAF 30/296 reads (10%) | catalogued as COSV59466182; called by muse, mutect2
- EFNA2 | c.534C>T p.Y178= | Silent (SNP) | VAF 35/158 reads (22%) | catalogued as rs140490619; called by muse, mutect2, varscan2
- GPR89A | c.51T>C p.F17= | Silent (SNP) | VAF 42/234 reads (18%) | called by muse, mutect2, varscan2
- IL4R | c.2376A>C p.S792= | Silent (SNP) | VAF 75/491 reads (15%) | catalogued as rs199986458; called by muse, mutect2, varscan2
- KIR3DL1 | c.108C>T p.S36= | Silent (SNP) | VAF 18/468 reads (4%) | called by muse, mutect2
- LCE2C | c.162C>T p.S54= | Silent (SNP) | VAF 112/515 reads (22%) | catalogued as COSV64228230; called by muse, mutect2, varscan2
- PCYOX1L | c.285C>G p.V95= | Silent (SNP) | VAF 81/411 reads (20%) | called by muse, mutect2, varscan2
- SEMA6C | c.201G>A p.L67= | Silent (SNP) | VAF 81/545 reads (15%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1047-3103G>A | Intron (SNP) | VAF 82/329 reads (25%) | catalogued as rs569857013; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821448 T>C | 3'Flank (SNP) | VAF 68/294 reads (23%) | called by muse, mutect2, varscan2
- DEFB130C | chr11:71865815 T>C | 3'Flank (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- KLF6 | c.*1957del | 3'UTR (DEL) | VAF 48/453 reads (11%) | called by mutect2, pindel, varscan2
- KRT12 | c.*29T>C | 3'UTR (SNP) | VAF 76/314 reads (24%) | called by muse, mutect2, varscan2
- NECTIN1 | c.79+14612G>T | Intron (SNP) | VAF 50/267 reads (19%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.569-2227_569-2225del | Intron (DEL) | VAF 33/140 reads (24%) | called by mutect2, pindel, varscan2
